Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5691, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5691-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

KIDNEY AND ADRENAL GLAND, LEFT, RADICAL NEPHRECTOMY-

KIDNEY:

- A. RENAL CELL CARCINOMA, CLEAR (CONVENTIONAL) CELL TYPE, FURMAN GRADE 3-4 (3.2 CM) (see comment).
- B. ALL SURGICAL MARGINS ARE FREE OF CARCINOMA.
- C. RENAL VEIN IS FREE OF CARCINOMA.
- D. THE CARCINOMA DOES NOT EXTEND BEYOND THE RENAL CAPSULE.
- E. TNM staging = pT1a Nx Mx.

ADRENAL GLAND:

- A. ADRENAL CORTICAL ADENOMA, 3.5 x 2.8 CM (see comment).
- B. NO EVIDENCE OF MALIGNANCY.

COMMENT:

The following immunohistochemical stains were performed on a section of the renal tumor (slide D), and the adrenal cortical adenoma (slide I), with the following results;

Vimentin;	negative in kidney,	negative in adrenal
Cytokeratin CAM 5.2;	positive in kidney,	negative in adrenal
Cytokeratin AE1/AE3;	positive in kidney,	negative in adrenal
EMA;	positive in kidney,	negative in adrenal
Inhibin;	negative in kidney,	positive in adrenal
Melan-A;	negative in kidney,	positive in adrenal
CD-10;	positive in kidney,	positive in adrenal
CD-34;	negative in kidney,	negative in adrenal (positive in background vessels in both).

The above immunohistochemical profile confirms these two neoplasms to be separate, i.e. the adrenal mass is not a metastasis of the renal cell carcinoma.

[page 2 of 2]
□ □ □ □ □

- A. Side: #2 1. Right 2. Left
- B. Location: #1
1. Kidney (parenchyma - cortex/medulla)
2. Kidney (pelvis)
- C. Procedure: #3
1. Partial nephrectomy
2. Simple nephrectomy
3. Radical nephrectomy
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): # 3.2cm
- E. Type of malignant neoplasm: #1
1. Renal cell carcinoma, clear cell type
(includes non-papillary granular cell RCC)
2. Renal cell carcinoma, chromophil cell type
(papillary RCC, no clear cell component)
3. Renal cell carcinoma, chromophobe cell type
4. Renal cell carcinoma, oncocytic
5. Renal cell carcinoma, sarcomatoid
6. Collecting duct carcinoma
7. Urothelial carcinoma, TCCa
(non-invasive)
8. Urothelial carcinoma, TCCa
(invasive ± in-situ)
9. Urothelial carcinoma, squamous carcinoma
10. Urothelial carcinoma, adenocarcinoma
- F. Histologic grade
F1. Fuhrman grade (for RCC; grades 1-4): #3/4
F2. Ash grade (grade 1-4): #
F3. WHO grade (grade 1-3): # (for TCCa)
F4.
1. LMP 2. LG 3. HG
F5. Other malignant neoplasms (grades 1-3): #
- G. Non-neoplastic and other conditions: # / # / # / #
1. Glomerulopathy
2. Interstitial nephritis
3. Pyelonephritis
4. Nephrolithiasis
5. Papillary necrosis
6. Chronic parenchymal disease
7. Other
- H. Margins of resection: #2
- I. Mitotic activity: # per 10 high power fields
- J. Angiolymphatic invasion
J1. Macroscopic (e.g., renal vein thrombus): #2
J2. Microscopic: #2
- K. Number of positive lymph nodes: #
- L. Total number of lymph nodes examined: #
- M. Extracapsular spread of lymph node metastases: #
1. Yes 2. No
- N. Adrenal gland:
N1. Present #1
N2. Involvement by renal neoplasm: #2
N3. Other adrenal pathology: 1 #
- O. TNM stage: T #1a Nx # M #x
3. Ureter
4. Kidney and ureter
4. Ureterectomy
5. Other
11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
12. Urothelial carcinoma, mixed
13. Juxtaglomerular cell tumor
14. Wilms' tumor
15. Rhabdoid tumor
16. Clear cell sarcoma
17. Congenital mesoblastic nephroma
18. Sarcoma (non-clear cell)
19. Lymphoma/leukemia
20. Other
1. Positive 2. Negative
1. Positive 2. Negative
1. Positive 2. Negative
1. Yes 2. No
1. Yes 2. No
1. Yes 2. No
1. Yes 2. No
3. Not Applicable
3. Not applicable

Source: NCI Genomic Data Commons file dc3ba3d8-26b9-40b9-a482-860f2af140fb (TCGA-B0-5691.6A7300F0-5029-45CE-BC46-00AF73774198.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).